Somatic mutation profile of tumor specimen TCGA-DY-A1DC-01A (aliquot TCGA-DY-A1DC-01A-31D-A152-10) from TCGA case TCGA-DY-A1DC, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.4 years (26,436 days).
Specimen TCGA-DY-A1DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea454c5-651e-43a7-9e6c-7e135a49e51d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DY-A1DC-10A (Blood Derived Normal), aliquot TCGA-DY-A1DC-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/905ef4aa-9888-46be-a594-5a817b7bc5aa

The open-access MAF lists 145 somatic variants for this specimen: 123 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 20, Nonsense Mutation 9, Splice Site 4, Splice Region 3, Frame Shift Ins 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4285C>T p.Q1429* | Nonsense Mutation (SNP) | VAF 47/87 reads (54%) | hotspot (GDC flag); catalogued as rs74535574, HM050024, COSV57322632, COSV57333893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 63/179 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 24/42 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AADAC | c.1173T>G p.Y391* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as COSV51760007; called by muse, mutect2, varscan2
- ABCA13 | c.11638G>A p.G3880R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775942969, COSV71290258; called by muse, mutect2, varscan2
- ABCA6 | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV52640278; called by muse, mutect2, varscan2
- ACOX2 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV57149562; called by muse, mutect2, varscan2
- ALDH1L1 | c.2392A>G p.M798V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1477060898, COSV99856418; called by muse, mutect2, varscan2
- ALLC | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52995521; called by muse, mutect2, varscan2
- ANGPT1 | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV52445005; called by muse, mutect2, varscan2
- ANKK1 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753165961, COSV58272550; called by muse, mutect2, varscan2
- ANTXR1 | c.359T>C p.M120T | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58015544; called by muse, mutect2, varscan2
- ARMC5 | c.2593G>A p.G865S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs1435809849, COSV51655805; called by muse, mutect2, varscan2
- C2CD6 | c.168C>G p.N56K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53796342; called by muse, mutect2, varscan2
- CARNS1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs756772834, COSV57051416; called by muse, mutect2, varscan2
- CBLL2 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 34/56 reads (61%) | catalogued as rs758361684, COSV60369368; called by muse, mutect2, varscan2
- CCM2 | c.473-1G>A p.X158_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | catalogued as COSV51849234, COSV51851585; called by muse, mutect2, varscan2
- CD93 | c.1940C>A p.T647K | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV55666185; called by muse, mutect2, varscan2
- CDH9 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370038496, COSV50308683; called by muse, mutect2, varscan2
- CEACAM18 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV67283277; called by muse, mutect2, varscan2
- COL11A1 | c.625A>T p.R209W | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62186965; called by muse, mutect2, varscan2
- COL5A1 | c.279G>A p.A93= | Splice Region (SNP) | VAF 32/100 reads (32%) | catalogued as rs145090868, COSV65670571; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- COL5A1 | c.5353C>A p.L1785M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV65670576; called by muse, mutect2, varscan2
- COL6A6 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 72/361 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs752996147, COSV62019642, COSV62023085; called by muse, mutect2, varscan2
- CRABP2 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs757917252, COSV63958981; called by mutect2, varscan2
- CROCC | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as COSV65012936; called by muse, mutect2, varscan2
- CYLD | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61095547; called by muse, mutect2
- CYP3A43 | c.80C>G p.T27S | Missense Mutation (SNP) | VAF 163/280 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55936681; called by muse, mutect2, varscan2
- DCLK1 | c.274A>C p.T92P | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55203814, COSV99708825; called by muse, mutect2, varscan2
- DENND4B | c.2075C>G p.P692R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV63410038; called by muse, mutect2, varscan2
- DNAH3 | c.9229C>T p.R3077C | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372316224; called by muse, mutect2, varscan2
- DUSP26 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs376826832, COSV56361434, COSV99823617; called by muse, mutect2, varscan2
- ELOVL6 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV56429921; called by muse, mutect2, varscan2
- EVC2 | c.1124G>C p.S375T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV60395915; called by muse, mutect2, varscan2
- EXOSC7 | c.255T>C p.C85= | Splice Region (SNP) | VAF 30/290 reads (10%) | catalogued as COSV99651765; called by muse, mutect2, varscan2
- FASN | c.6229G>A p.D2077N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs141935205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FEM1B | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV60988822; called by muse, mutect2, varscan2
- FGF8 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV60143077; called by muse, mutect2, varscan2
- FREM2 | c.6773T>C p.F2258S | Missense Mutation (SNP) | VAF 109/265 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV54841815; called by muse, mutect2, varscan2
- GFRA3 | c.889+1G>A p.X297_splice | Splice Site (SNP) | VAF 60/156 reads (38%) | catalogued as COSV51229142, COSV51229269; called by muse, mutect2, varscan2
- GJB4 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as COSV58356462; called by muse, mutect2, varscan2
- GPR63 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as rs146501968; called by muse, mutect2, varscan2
- HCN4 | c.1800C>A p.D600E | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV56084611; called by muse, mutect2, varscan2
- HPSE2 | c.1527G>T p.K509N | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV65192194; called by muse, mutect2, varscan2
- HSPA8 | c.202T>A p.F68I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV57084445; called by muse, mutect2, varscan2
- HYDIN | c.13558G>A p.G4520S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200437208; called by muse, mutect2, varscan2
- IFNK | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as COSV51782469; called by muse, mutect2, varscan2
- ILVBL | c.144G>C p.K48N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV54620531; called by muse, mutect2, varscan2
- IST1 | c.976C>T p.P326S (on ENST00000535424 / NM_001270976.1; = p.F311= on NM_014761.4) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100324490; called by muse, mutect2, varscan2
- KCND3 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56175499; called by muse, mutect2, varscan2
- KDM4B | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.45); PolyPhen benign (0.318); catalogued as COSV50227169; called by muse, mutect2, varscan2
- KDM5A | c.4211C>A p.S1404Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.986); catalogued as COSV66993594; called by muse, mutect2, varscan2
- KIF5A | c.2183T>C p.I728T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs757751684, COSV54055885; called by muse, mutect2, varscan2
- KRTAP10-1 | c.481T>G p.S161A | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV59967337; called by muse, mutect2, varscan2
- LAMA1 | c.5702G>T p.S1901I | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV67539125; called by muse, mutect2, varscan2
- LAMA1 | c.3332G>C p.C1111S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67539128; called by muse, mutect2, varscan2
- LRRK2 | c.3224T>G p.V1075G | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV54157524; called by muse, mutect2, varscan2
- MSTN | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV53621416; called by muse, mutect2, varscan2
- MYH13 | c.3863_3864insC p.G1289Wfs*32 | Frame Shift Ins (INS) | VAF 103/199 reads (52%) | catalogued as COSV52832828; called by mutect2, pindel, varscan2
- NAGA | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV67170034; called by muse, mutect2, varscan2
- NBAS | c.1801G>C p.E601Q | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); catalogued as COSV55726257; called by muse, mutect2, varscan2
- NEK11 | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs145914506, COSV101272951; called by muse, mutect2, varscan2
- NEK4 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51781117; called by muse, mutect2, varscan2
- NHLRC3 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV61488226; called by muse, mutect2, varscan2
- OLFM3 | c.1165T>C p.Y389H (on ENST00000338858 / NM_001288821.1; = p.Y369H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV58800207; called by muse, mutect2, varscan2
- OR2T3 | c.905T>A p.V302D | Missense Mutation (SNP) | VAF 147/859 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100613026; called by muse, mutect2, varscan2
- OR4K5 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60003984, COSV60004319; called by muse, mutect2
- OR6S1 | c.12T>A p.D4E | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57838498; called by muse, mutect2, varscan2
- OR7A5 | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV59234819; called by muse, mutect2, varscan2
- PAH | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61017587; called by muse, mutect2, varscan2
- PAPPA2 | c.1912G>A p.D638N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1168232006, COSV62772967; called by muse, mutect2, varscan2
- PDE5A | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 151/424 reads (36%) | catalogued as COSV53349463; called by muse, mutect2, varscan2
- PLA2G4F | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766258609, COSV51827566; called by muse, mutect2, varscan2
- PNLIPRP3 | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 41/122 reads (34%) | catalogued as COSV65047376, COSV65048662; called by muse, mutect2, varscan2
- PNPLA6 | c.3604C>T p.R1202C (on ENST00000414982 / NM_001166111.2; = p.R1154C on NM_006702.5) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55380073; called by muse, mutect2, varscan2
- PPP1R15A | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52339432; called by muse, mutect2, varscan2
- PRKAR1A | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs1568695288, COSV62235110; called by muse, mutect2
- PROM1 | c.2330C>A p.T777N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV71699574; called by muse, mutect2, varscan2
- PSMC1 | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV54321140; called by muse, mutect2, varscan2
- PTK2 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 153/251 reads (61%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100569272; called by muse, varscan2
- PTPRB | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs759344115, COSV51736337; called by muse, mutect2, varscan2
- RNASEH2A | c.324-1G>A p.X108_splice | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as COSV55552139; called by muse, mutect2, varscan2
- ROS1 | c.5594C>T p.T1865I | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100877789, COSV63856752; called by muse, mutect2, varscan2
- RRP8 | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1230783061, COSV54449995; called by muse, mutect2, varscan2
- RTEL1 | c.2944C>G p.H982D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV58896329; called by muse, mutect2, varscan2
- SDCCAG8 | c.1061A>T p.K354I | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100653743; called by muse, mutect2
- SDCCAG8 | c.1063A>T p.T355S | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100653745; called by muse, mutect2
- SENP1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs771938522, COSV50293323; called by muse, mutect2, varscan2
- SIPA1L1 | c.4925G>C p.G1642A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs1449623843, COSV62168795, COSV62173396; called by muse, mutect2, varscan2
- SMAD2 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV100053261; called by muse, mutect2, varscan2
- SMAD3 | c.857C>G p.T286R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100528624; called by muse, mutect2, varscan2
- SNX14 | c.2537C>A p.S846* (on ENST00000314673 / NM_001350535.1; = p.S793* on NM_020468.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as COSV59011125, COSV59013532; called by muse, mutect2, varscan2
- SPOCD1 | c.2263G>A p.D755N | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV57095753; called by muse, mutect2, varscan2
- SPOCK3 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 120/801 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.984); catalogued as COSV62728715; called by muse, mutect2, varscan2
- SPTAN1 | c.4225G>A p.G1409R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs746913959, COSV63985742, COSV63987423; called by muse, mutect2, varscan2
- TCHH | c.582G>C p.Q194H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV64275648; called by muse, mutect2, varscan2
- TDO2 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV72483907; called by muse, mutect2, varscan2
- TEX14 | c.2195T>A p.L732H (on ENST00000240361 / NM_001201457.2; = p.L726H on NM_031272.5) | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs1447471007, COSV53619767; called by muse, mutect2, varscan2
- TNFSF4 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs1436185083, COSV56056814; called by muse, mutect2, varscan2
- TNS4 | c.2135C>A p.A712E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as COSV54185842; called by muse, mutect2, varscan2
- TRAM1 | c.1120T>C p.S374P | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV51598773; called by muse, mutect2, varscan2
- TRIM24 | c.2155C>T p.P719S (on ENST00000343526 / NM_015905.3; = p.P685S on NM_003852.4) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.113); catalogued as COSV58973704; called by muse, mutect2, varscan2
- TRIP11 | c.4814G>C p.R1605T | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV50929776; called by muse, mutect2, varscan2
- TRPM8 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs201008719, COSV61220863; called by muse, mutect2, varscan2
- TSHZ2 | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 81/136 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs749112887, COSV61589512; called by muse, mutect2, varscan2
- TTC3 | c.2615A>T p.Y872F | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.01); catalogued as COSV61292028; called by muse, mutect2, varscan2
- TTN | c.90511G>A p.G30171S (on ENST00000591111; = p.G22747S on NM_003319.4) | Missense Mutation (SNP) | VAF 69/229 reads (30%) | PolyPhen probably damaging (0.999); catalogued as rs754416007, COSV60145867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.47957G>T p.R15986L (on ENST00000591111; = p.R8562L on NM_003319.4) | Missense Mutation (SNP) | VAF 83/225 reads (37%) | PolyPhen benign (0.03); catalogued as COSV60145901; called by muse, mutect2, varscan2
- UBR2 | c.2263T>C p.Y755H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV65750664; called by muse, mutect2, varscan2
- USP28 | c.610C>G p.R204G | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV50161045, COSV50168231, COSV99134605; called by muse, mutect2, varscan2
- UXS1 | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51679110; called by muse, mutect2, varscan2
- VWF | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1365449398, COSV54624447; called by muse, mutect2, varscan2
- XRN1 | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs781322995, COSV53813734, COSV99377841; called by muse, mutect2, varscan2
- ZC3H12A | c.349A>T p.K117* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV66104194; called by muse, mutect2
- ZDHHC15 | c.165T>C p.V55= | Splice Region (SNP) | VAF 8/42 reads (19%) | catalogued as COSV64902367; called by muse, mutect2, varscan2
- ZFAND4 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58897618; called by muse, mutect2, varscan2
- ZFHX4 | c.6538A>G p.T2180A | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51447480; called by muse, mutect2, varscan2
- ZIC1 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51554952; called by muse, mutect2, varscan2
- ZMAT3 | c.691A>T p.R231* | Nonsense Mutation (SNP) | VAF 25/115 reads (22%) | catalogued as COSV60993933; called by muse, mutect2, varscan2
- ZNF22 | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100026485; called by muse, mutect2, varscan2
- ZNF594 | c.2286G>T p.W762C | Missense Mutation (SNP) | VAF 76/117 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV68385628; called by muse, mutect2, varscan2
- DPEP1 | c.338dup p.E114Gfs*34 | Frame Shift Ins (INS) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- PTPRG | c.612dup p.Q205Sfs*24 | Frame Shift Ins (INS) | VAF 43/323 reads (13%) | called by mutect2, pindel, varscan2
- AC098582.1 | c.1722A>G p.R574= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as COSV52021456; called by muse, mutect2, varscan2
- AHNAK2 | c.13452C>T p.V4484= | Silent (SNP) | VAF 85/147 reads (58%) | catalogued as COSV60919021; called by muse, mutect2, varscan2
- C10orf90 | c.696C>A p.T232= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1470025442, COSV52957646; called by muse, mutect2, varscan2
- CFH | c.1488A>G p.K496= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as COSV100808651; called by muse, mutect2, varscan2
- DOP1A | c.2835A>T p.I945= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV52712276; called by muse, mutect2, varscan2
- HIPK4 | c.1053G>A p.Q351= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52522025; called by muse, mutect2, varscan2
- IFT140 | c.1029C>T p.T343= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs556379159, COSV68485725; called by muse, mutect2, varscan2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs369104625; called by muse, mutect2, varscan2
- MAGI1 | c.372T>C p.S124= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV58332258; called by muse, mutect2, varscan2
- NUCB1 | c.660C>T p.N220= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1254997406, COSV99617651; called by mutect2, varscan2
- OR2C3 | c.504G>A p.P168= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs544163828, COSV63575307; called by muse, mutect2, varscan2
- PCDHA5 | c.2043G>A p.A681= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV65353034; called by muse, mutect2, varscan2
- PI15 | c.378T>A p.S126= | Silent (SNP) | VAF 41/211 reads (19%) | catalogued as COSV52642393; called by muse, mutect2, varscan2
- PIK3R3 | c.1275G>A p.L425= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs1000424074, COSV53108512; called by muse, mutect2, varscan2
- PKHD1 | c.4695T>C p.V1565= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV61881944; called by muse, mutect2
- PLSCR1 | c.672A>G p.R224= | Silent (SNP) | VAF 126/623 reads (20%) | catalogued as rs201312426, COSV61013077; called by muse, mutect2, varscan2
- TMEM131 | c.3969C>T p.P1323= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs769940373, COSV51778614; called by muse, mutect2, varscan2
- WDR19 | c.129C>A p.R43= | Silent (SNP) | VAF 65/212 reads (31%) | catalogued as COSV56466539; called by muse, mutect2, varscan2
- ZNF558 | c.1146G>A p.G382= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as COSV100037794; called by muse, mutect2, varscan2
- ZSCAN1 | c.609C>A p.S203= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV56605607, COSV56606144, COSV56607804; called by muse, mutect2
- CSMD3 | c.178+59923C>T | Intron (SNP) | VAF 6/81 reads (7%) | catalogued as COSV99822554; called by muse, mutect2
- EIF4A2 | c.771+48T>G | Intron (SNP) | VAF 26/277 reads (9%) | catalogued as COSV99960958; called by muse, mutect2
